Somatic mutation profile of tumor specimen TARGET-40-0A4I65-01A (aliquot TARGET-40-0A4I65-01A-01D) from TARGET case TARGET-40-0A4I65, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.9 years (6,520 days).
Specimen TARGET-40-0A4I65-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76d4432e-e53f-4730-a4da-0b07b7ed3f88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I65-10A (Blood Derived Normal), aliquot TARGET-40-0A4I65-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a52d26d-8272-44bb-8518-613fa81877dc

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Intron 4, Splice Site 3, 3'UTR 2, RNA 2, 3'Flank 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF12 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV63106027; called by muse, mutect2, varscan2
- GPAT4 | c.1054-2A>C p.X352_splice | Splice Site (SNP) | VAF 71/187 reads (38%) | catalogued as COSV67841061; called by muse, mutect2, varscan2
- LRIT1 | c.987A>C p.Q329H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV64513656; called by muse, mutect2, varscan2
- OR1M1 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376976283; called by muse, mutect2, varscan2
- SLC46A2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201803107; called by muse, mutect2
- SLU7 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs971318091, COSV99775797; called by muse, mutect2
- TNNI3K | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs747300364, COSV58547042; called by muse, mutect2, varscan2
- TNNT1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs139279150, COSV52570783; called by muse, mutect2, varscan2
- WDR24 | c.2374G>A p.E792K (on ENST00000248142; = p.E662K on NM_032259.4) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs767524698; called by muse, mutect2, varscan2
- XPO6 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV58966708; called by muse, mutect2
- ADGRE2 | c.1926C>A p.F642L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- BMP3 | c.1274C>A p.A425D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1B | c.4949+1G>C p.X1650_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- DDIT4L | c.88A>T p.S30C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- GLYR1 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GRK7 | c.779G>C p.S260T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HNRNPL | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV2-30 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MAG | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- MYCL | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POGLUT2 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPARA | c.820C>A p.H274N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SLC1A6 | c.1607T>A p.L536H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPATA31A3 | c.2702G>T p.G901V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- SPATA31A6 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SUGP2 | c.1379G>C p.S460T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- TG | c.4060G>T p.V1354L | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.029); called by muse, mutect2
- TRIM46 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- YPEL2 | c.270+2T>G p.X90_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- ZCCHC12 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF334 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2
- ACSS1 | c.453C>T p.C151= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs147035244; called by muse, mutect2, varscan2
- PARP12 | c.1038T>C p.F346= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- PCDHA6 | c.474C>T p.S158= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs782536026, COSV100972213; called by muse, mutect2, varscan2
- RP1L1 | c.2106A>G p.P702= | Silent (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1240C>A p.R414= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV56769290; called by muse, mutect2, varscan2
- SMAD4 | c.876G>A p.P292= | Silent (SNP) | VAF 73/117 reads (62%) | catalogued as rs753358186; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- THAP7 | c.133C>A p.R45= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10832C>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1444-19C>G | Intron (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- CD5L | c.*67G>C | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, varscan2
- DCHS2 | n.5448G>T | RNA (SNP) | VAF 28/40 reads (70%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2184738 G>C | 3'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- JAML | c.772+81T>C | Intron (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- NUDT3 | c.*12C>G | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20896110 G>T | 5'Flank (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- SGSM2 | c.2475-145C>T | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2
- SNORD115-36 | n.68A>G | RNA (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
